Somatic mutation profile of tumor specimen C3L-01662-03 (aliquot CPT0092630009) from CPTAC case C3L-01662, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.2 years (21,979 days).
Specimen C3L-01662-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97fe3756-cb00-4432-857a-c659bf06f770.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01662-31 (Blood Derived Normal), aliquot CPT0093720002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/476cd2a4-2af8-4b1f-94db-17a6338b76b7

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 10 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 10, Nonsense Mutation 3, Intron 3, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 71/438 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FMN2 | c.5028G>A p.W1676* | Nonsense Mutation (SNP) | VAF 14/280 reads (5%) | catalogued as COSV60446025; called by muse, mutect2
- GPR63 | c.232T>A p.L78M | Missense Mutation (SNP) | VAF 21/416 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV57742225; called by muse, mutect2
- OBSCN | c.12664G>A p.V4222M | Missense Mutation (SNP) | VAF 99/456 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs375322738; called by muse, mutect2, varscan2
- PROP1 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 28/446 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.129); catalogued as rs374712664; called by muse, mutect2
- PRRC2A | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 28/369 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100784513; called by muse, mutect2
- SYNE2 | c.9602C>T p.A3201V | Missense Mutation (SNP) | VAF 18/382 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs1321728968; called by muse, mutect2
- TAS1R2 | c.1417C>T p.R473* | Nonsense Mutation (SNP) | VAF 30/368 reads (8%) | catalogued as rs1020801784, COSV64744730; called by muse, mutect2
- TBC1D10B | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.594); catalogued as rs747731612; called by muse, mutect2, varscan2
- TRIM42 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766965674, COSV53883946; called by muse, mutect2
- BDP1 | c.5089G>A p.E1697K | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.037); called by muse, mutect2
- GLI3 | c.1442A>C p.N481T | Missense Mutation (SNP) | VAF 44/500 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2
- HNF1A | c.592A>T p.K198* | Nonsense Mutation (SNP) | VAF 28/562 reads (5%) | called by muse, mutect2
- IGKV1D-43 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 29/326 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.409); called by muse, mutect2
- LIG3 | c.1167G>C p.K389N | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MTCL1 | c.3041T>A p.L1014H (on ENST00000306329 / NM_001378206.1; = p.L695H on NM_015210.4) | Missense Mutation (SNP) | VAF 42/532 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NTF3 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 38/430 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- PPARA | c.332G>C p.G111A | Missense Mutation (SNP) | VAF 110/630 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PXDNL | c.534T>G p.D178E | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- RGS4 | c.155G>C p.S52T | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- SLITRK2 | c.313dup p.A105Gfs*19 | Frame Shift Ins (INS) | VAF 50/388 reads (13%) | called by mutect2, pindel, varscan2
- SPAG16 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.059); called by muse, mutect2
- TUBGCP3 | c.1482C>G p.H494Q | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.216); called by muse, mutect2
- ZNF793 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF800 | c.1540A>T p.I514F | Missense Mutation (SNP) | VAF 22/242 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); called by muse, mutect2
- CSMD3 | c.4632A>G p.R1544= (on ENST00000297405 / NM_001363185.1; = p.R1440= on NM_052900.3) | Silent (SNP) | VAF 30/439 reads (7%) | called by muse, mutect2
- DOT1L | c.2550G>C p.L850= | Silent (SNP) | VAF 10/174 reads (6%) | catalogued as COSV101288490; called by muse, mutect2
- MUC5B | c.13113C>T p.T4371= | Silent (SNP) | VAF 63/652 reads (10%) | catalogued as COSV71589938; called by muse, mutect2
- NAALADL2 | c.465A>C p.P155= | Silent (SNP) | VAF 12/350 reads (3%) | called by muse, mutect2
- NEXMIF | c.1983C>T p.H661= | Silent (SNP) | VAF 48/384 reads (13%) | catalogued as rs138583612, COSV50138448; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR1N1 | c.579C>T p.N193= | Silent (SNP) | VAF 30/353 reads (8%) | called by muse, mutect2
- PCNX3 | c.1623G>C p.L541= | Silent (SNP) | VAF 17/250 reads (7%) | catalogued as COSV58418205; called by muse, mutect2
- RB1CC1 | c.273C>G p.T91= | Silent (SNP) | VAF 25/208 reads (12%) | called by muse, mutect2, varscan2
- SYT8 | c.1125C>T p.P375= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as rs765027292, COSV53290837; called by muse, mutect2, varscan2
- TAP2 | c.507C>T p.I169= | Silent (SNP) | VAF 35/650 reads (5%) | called by muse, mutect2
- CCDC50 | c.448+17C>T | Intron (SNP) | VAF 19/487 reads (4%) | called by muse, mutect2
- KIR3DX1 | n.864C>T | RNA (SNP) | VAF 28/388 reads (7%) | catalogued as rs760842823, COSV55597926; called by muse, mutect2
- MASP1 | c.1303+5028C>T | Intron (SNP) | VAF 14/199 reads (7%) | catalogued as rs750601815, COSV56227201; called by muse, mutect2
- VSTM2A | c.634+3902A>G | Intron (SNP) | VAF 18/227 reads (8%) | catalogued as rs1447061657; called by muse, mutect2
